Somatic mutation profile of cancer-model specimen HCM-CSHL-0393-C18-85A (3D Organoid, passage 4; aliquot HCM-CSHL-0393-C18-85A-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0393-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, undifferentiated, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G4.
Specimen HCM-CSHL-0393-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0359f71-ff5f-4beb-bc7b-8eb67a39235e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0393-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0393-C18-11A-11D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a4be5a3-477a-42a9-9ceb-19fd796550d6

The open-access MAF lists 36 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLG5 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 17/482 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1460201893; called by muse, mutect2
- ECPAS | c.1873C>G p.R625G | Missense Mutation (SNP) | VAF 83/610 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV99398885; called by muse, mutect2, varscan2
- NOL10 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 15/366 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV62040676; called by muse, mutect2
- OR2M3 | c.255C>A p.Y85* | Nonsense Mutation (SNP) | VAF 101/1038 reads (10%) | catalogued as rs1321429294; called by muse, mutect2
- OR4C12 | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 67/372 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV58859350; called by muse, mutect2, varscan2
- OR5L2 | c.270A>C p.K90N | Missense Mutation (SNP) | VAF 24/589 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1225804003; called by muse, mutect2
- PREX2 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 29/502 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs773432628, COSV55807952; called by muse, mutect2
- RAB11FIP2 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.7); catalogued as rs958187622, COSV62926240; called by muse, mutect2, varscan2
- RFX6 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.039); catalogued as COSV60584885; called by muse, mutect2, varscan2
- SPTA1 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 33/569 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63755797; called by muse, mutect2
- SUMF2 | c.574G>A p.A192T (on ENST00000652303; = p.A173T on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs763375716, COSV51919418; called by muse, mutect2
- ACAP1 | c.1792G>C p.V598L | Missense Mutation (SNP) | VAF 46/711 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- AMIGO2 | c.1166G>C p.R389T | Missense Mutation (SNP) | VAF 18/597 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- CERS5 | c.197+1G>C p.X66_splice | Splice Site (SNP) | VAF 20/518 reads (4%) | called by muse, mutect2
- CNGA1 | c.927G>C p.W309C | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CYP2A6 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 36/996 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- MAP7D3 | c.2066A>C p.E689A | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- MYH8 | c.1500G>C p.E500D | Missense Mutation (SNP) | VAF 23/518 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2
- NCDN | c.1916T>G p.L639R | Missense Mutation (SNP) | VAF 28/789 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NOC4L | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 24/677 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.058); called by muse, mutect2
- OOSP3 | c.487T>A p.F163I | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.514); called by muse, mutect2
- OR2L5 | c.778T>A p.C260S | Missense Mutation (SNP) | VAF 35/419 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2
- PSG5 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 56/467 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- REPS2 | c.1353C>G p.N451K | Missense Mutation (SNP) | VAF 146/204 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, varscan2
- RPGRIP1L | c.882+1G>A p.X294_splice | Splice Site (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2, varscan2
- SLC6A18 | c.947C>A p.T316N | Missense Mutation (SNP) | VAF 22/363 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2
- SOX3 | c.781_819del p.Y261_S273del | In Frame Del (DEL) | VAF 71/341 reads (21%) | called by mutect2, pindel, varscan2
- SRP54 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- TTC34 | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 18/736 reads (2%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.902); called by muse, mutect2
- ZBTB18 | c.1074C>G p.Y358* | Nonsense Mutation (SNP) | VAF 68/654 reads (10%) | called by muse, mutect2, varscan2
- CACNA1H | c.627C>T p.A209= | Silent (SNP) | VAF 60/698 reads (9%) | called by muse, mutect2
- DNAAF5 | c.234G>T p.L78= | Silent (SNP) | VAF 26/704 reads (4%) | called by muse, mutect2
- IFI16 | c.811C>T p.L271= | Silent (SNP) | VAF 40/596 reads (7%) | called by muse, mutect2
- TDRD1 | c.3426C>T p.C1142= | Silent (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2, varscan2
- TMEM259 | c.60C>T p.G20= | Silent (SNP) | VAF 96/562 reads (17%) | called by mutect2, varscan2
- PHF10 | chr6:169725121 G>C | 5'Flank (SNP) | VAF 17/562 reads (3%) | called by muse, mutect2
